CCDI case PBBZXE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2474da50-cb5e-4d20-afb2-e8c3def3b881

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,152 days).

Biospecimens (3 samples)
- Sample 0DPBF8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPBFQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPBGB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
